Gene-level copy-number profile of tumor specimen TCGA-06-0210-02A from TCGA case TCGA-06-0210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.8 years (26,600 days).
Specimen TCGA-06-0210-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c9d200e4-3f65-4474-b4ba-d1b1d7d1bd43.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0210-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a492121f-3bae-416e-9c99-c8342c50c3be

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 611; copy number 1: 58; copy number 2: 5,369; copy number 3: 21,906; copy number 4: 28,548; copy number 5: 767; copy number 6: 391; copy number 7: 2,559; copy number 10: 14; copy number 11: 4; copy number 12: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0210-02A-01D-2002-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr4:68,509,441–68,616,137, 4 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr9:20,999,509–23,438,700, 60 genes (within-gene range 0–2): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:21,756,548–22,003,769, 1 gene (within-gene range 0–2): DNAJC1.
- chr10:21,865,335–22,787,499, 24 genes: AL359697.1, RN7SKP37, ADIPOR1P1, AL157831.1, EBLN1, AL157831.2, PSME2P6, AL157831.3, AL158211.5, AL158211.1, RPL31P45, COMMD3, COMMD3-BMI1, BMI1, AL158211.4, AL158211.2, AL158211.3, SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,318,996–204,829,274, 48 genes, copy number 12: RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1.
- chr4:53,377,839–54,295,272, 1 gene, copy number 10 (within-gene range 4–10): AC058822.1.
- chr4:53,899,871–54,355,954, 13 genes, copy number 10 (within-gene range 7–10): AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283.
- chr4:62,816,826–63,529,761, 4 genes, copy number 11: EXOC5P1, AC097491.1, LARP1BP1, AC093730.1.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
